CCDI case PBBZGY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/6e26ce2d-aaa8-44a7-a6be-6b4c0f64465b

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,479 days).

Biospecimens (2 samples)
- Sample 0DLV2W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLV36: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
